Gene-level copy-number profile of specimen HCM-SANG-0551-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0551-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0551-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1ee8f4ab-ef1e-42e7-a556-b9cdf46481e7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0551-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/e5bb5c2d-71d5-407e-bb93-7a78951ae4d8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,494; copy number 2: 44,281; copy number 3: 10,543; copy number 4: 3; copy number 7: 16; copy number 13: 10; copy number 14: 29.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:203,706,475–206,796,189, 54 genes, copy number 7–14: CD28, KRT18P39, NPM1P33, RNU6-474P, CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1, AC016903.1, AC016903.2, PARD3B, AC007736.1, AC008171.1, NRP2, AC007362.1, RN7SKP178, PPIAP68, AC007679.1, INO80D, Vault, Y_RNA, RPL27P8, AC007383.1, NDUFS1, AC007383.2, GCSHP3, EEF1B2, AC007383.3, snoZ196, SNORD51, SNORA41, GPR1, GPR1-AS, RN7SKP200, ATP5POP1, HMGN1P6, RN7SKP260, ZDBF2, ACER2P1, HNRNPA1P51, ADAM23, AC010731.1, AC010731.2, FAM237A, DYTN, VPS26CP1, Y_RNA, MDH1B, FASTKD2, MIR3130-2, MIR3130-1.
- chr2:206,821,190–206,822,294, 1 gene, copy number 14: AC008269.2.

Autosomal genes at a single copy (total copy number 1): 3,494. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
